Surgical pathology report (de-identified scan), TCGA case TCGA-22-4591, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-4591-01A (Primary Tumor).

Surgical Pathology

TISSUE DESCRIPTION:

Right lower lobe lung (370 grams; 18 x 18 x 4.5 cm), superior mediastinal (right lower paratracheal) and inferior mediastinal (subcarinal) lymph nodes

DIAGNOSIS:

Lung, right lower lobe, lobectomy: Cavitory grade 3 (of 4) squamous cell carcinoma, located peripherally, forming a 7.5 x 6.0 x 5.5 cm mass, invading into but not through the visceral pleura. The bronchial margins and three intrapulmonary peribronchial lymph nodes are negative for malignancy.

Lymph nodes, inferior mediastinal, excision: Multiple 3 (of 9) subcarinal lymph nodes are positive for metastatic grade 3 (of 4) squamous cell carcinoma.

Lymph nodes, superior mediastinal, excision: Multiple superior mediastinal (6 right lower paratracheal) lymph nodes are negative for tumor.

Source: NCI Genomic Data Commons file d24aa67f-6323-4391-9928-dd9d607e53c8 (TCGA-22-4591.97A5B9F1-AC4B-4744-ABD9-03CCF04D1892.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).